Gene-level copy-number profile of tumor specimen ALCH-B2FA-TTP1-A from ALCHEMIST case ALCH-B2FA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.6 years (20,311 days).
Specimen ALCH-B2FA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 89d6ffa4-6284-4eb7-8461-2fc490f1fa15.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2FA-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/4028a66f-9d3f-413f-9afa-e5efd2756881

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 82; copy number 1: 13,093; copy number 2: 43,418; copy number 3: 1,593; copy number 4: 13; copy number 5: 52; copy number 6: 129; copy number 7: 2; copy number 10: 1; copy number 27: 5.

Homozygous deletions (total copy number 0; autosomes only): 82 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,693,124–7,694,844, 1 gene (within-gene range 0–1): AL359881.3.
- chr1:12,567,910–12,618,210, 3 genes: DHRS3, RNU6ATAC18P, MIR6730.
- chr1:32,717,734–32,725,237, 1 gene: AC114489.1.
- chr2:72,932,974–72,934,355, 1 gene (within-gene range 0–2): AC012366.1.
- chr2:131,491,160–131,491,236, 1 gene (within-gene range 0–2): MIR4784.
- chr2:241,544,403–241,558,977, 1 gene (within-gene range 0–2): BOK-AS1.
- chr3:50,191,610–50,197,696, 1 gene: GNAT1.
- chr3:75,384,059–75,422,143, 4 genes (within-gene range 0–1): AC139453.2, LSP1P2, AC139453.1, ALG1L6P.
- chr3:196,999,460–197,004,744, 1 gene (within-gene range 0–2): MELTF-AS1.
- chr4:625,573–670,782, 3 genes: PDE6B, PDE6B-AS1, AC107464.2.
- chr8:144,477,969–144,505,444, 2 genes (within-gene range 0–1): PPP1R16A, AC084125.2.
- chr8:144,517,992–144,529,132, 3 genes: LRRC14, LRRC24, C8orf82.
- chr9:125,372,325–125,372,766, 1 gene: AL627223.1.
- chr9:129,094,794–129,111,189, 2 genes (within-gene range 0–1): CRAT, AL158151.2.
- chr9:136,542,881–136,549,893, 3 genes (within-gene range 0–2): AL592301.1, MIR4674, NALT1.
- chr10:97,828,478–97,849,798, 1 gene: LINC00866.
- chr12:47,960,497–48,004,554, 3 genes: AC004801.7, TMEM106C, COL2A1.
- chr12:121,804,009–121,832,656, 1 gene: SETD1B.
- chr13:110,613,082–110,639,993, 2 genes: AL139385.1, NAXD.
- chr13:110,712,736–110,723,339, 1 gene (within-gene range 0–1): ING1.
- chr14:73,537,143–73,633,941, 8 genes (within-gene range 0–1): ACOT1, NT5CP2, AC005225.2, ACOT2, NT5CP1, AC005225.4, ACOT4, ACOT6.
- chr14:104,769,349–104,770,271, 1 gene (within-gene range 0–1): AL583722.1.
- chr15:25,180,497–25,193,402, 8 genes (within-gene range 0–1): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13.
- chr15:25,204,357–25,236,166, 18 genes (within-gene range 0–1): SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36.
- chr17:404,468–511,347, 4 genes (within-gene range 0–2): AC141424.1, C17orf97, RFLNB, AC015853.2.
- chr17:28,256,375–28,266,369, 3 genes: AC061975.2, AC061975.4, AC061975.1.
- chr18:37,273,706–37,276,572, 1 gene (within-gene range 0–1): AC090386.1.
- chr19:53,793,741–53,824,394, 1 gene: NLRP12.
- chr20:63,861,212–63,864,293, 2 genes: AL118506.1, ABHD16B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 189 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–31,109, 5 genes, copy number 27: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2.
- chr1:146,064,711–148,093,883, 52 genes, copy number 5 (within-gene range 3–5): NBPF10, NOTCH2NLA, AC239799.1, RNU6-1071P, NUDT4P2, SEC22B4P, PPIAL4H, RNVU1-29, RNVU1-25, AC245407.1, HYDIN2, RNA5SP536, AC241929.1, NBPF12, PFN1P8, AC244394.3, AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1.
- chr1:149,754,301–151,831,845, 123 genes, copy number 6 (broad region; genes not listed).
- chr17:18,426,861–18,475,920, 6 genes, copy number 6: KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2.
- chr21:43,446,601–43,479,534, 3 genes, copy number 7–10: LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 12,218. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
